Somatic mutation profile of tumor specimen TCGA-DG-A2KM-01A (aliquot TCGA-DG-A2KM-01A-11D-A17W-09) from TCGA case TCGA-DG-A2KM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 46.0 years (16,808 days).
Specimen TCGA-DG-A2KM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35e37b4f-53c7-4a89-a0c8-363757391d3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DG-A2KM-10A (Blood Derived Normal), aliquot TCGA-DG-A2KM-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddbbc3db-e136-4ba5-90cd-d21f4de9b620

The open-access MAF lists 180 somatic variants for this specimen: 128 protein-altering or splice-affecting, 48 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 48, Nonsense Mutation 10, Splice Site 3, Intron 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC131160.1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as rs749633030, COSV57701998; called by muse, mutect2, varscan2
- ADAMDEC1 | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 11/131 reads (8%) | catalogued as COSV56476318, COSV99836327; called by muse, mutect2
- ADGRA1 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1430068082, COSV66927033; called by muse, mutect2
- ADGRV1 | c.6586G>A p.E2196K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67993573; called by muse, mutect2, varscan2
- AGO4 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64617058, COSV64618358; called by muse, mutect2
- AGRN | c.3610G>C p.V1204L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV65071935; called by muse, mutect2, varscan2
- AKAP4 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV100654371; called by muse, mutect2
- ALDH1A1 | c.1492C>G p.Q498E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52790923; called by muse, mutect2, varscan2
- ALPK2 | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV100864462, COSV64496191; called by muse, mutect2, varscan2
- AMOTL2 | c.2236G>C p.D746H (on ENST00000422605; = p.D747H on NM_016201.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); catalogued as COSV51440519; called by muse, mutect2, varscan2
- ANK3 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237003056, COSV99782447; called by muse, mutect2
- ATP10A | c.3229C>T p.H1077Y | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63522454; called by muse, mutect2, varscan2
- C2CD6 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV53799489; called by muse, mutect2, varscan2
- CABIN1 | c.3573C>G p.F1191L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV54087868; called by muse, mutect2, varscan2
- CACUL1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.043); catalogued as rs926398363, COSV60996373; called by muse, mutect2, varscan2
- CBLL2 | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV60370041; called by muse, mutect2, varscan2
- CCNB3 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.071); catalogued as COSV52078682; called by muse, mutect2, varscan2
- CCP110 | c.2162C>G p.S721C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV101195222, COSV66817902; called by muse, mutect2
- CD44 | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99556026; called by muse, mutect2
- CDH26 | c.1125G>C p.R375S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as COSV54846037, COSV99722997; called by muse, mutect2
- CDK12 | c.3205G>C p.E1069Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); catalogued as COSV71000857; called by muse, mutect2, varscan2
- CFAP69 | c.2266-1G>A p.X756_splice | Splice Site (SNP) | VAF 7/64 reads (11%) | catalogued as COSV60187807; called by muse, mutect2, varscan2
- CFAP74 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.098); catalogued as COSV54572758; called by muse, mutect2, varscan2
- CHUK | c.1395G>C p.M465I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV64918593; called by muse, mutect2, varscan2
- COBLL1 | c.3346G>C p.D1116H (on ENST00000392717; = p.D1078H on NM_014900.5) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52074871; called by muse, mutect2, varscan2
- CORO1A | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99532217; called by muse, mutect2
- CPNE1 | c.1071G>C p.L357F (on ENST00000352393; = p.L362F on NM_003915.5) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100468133; called by muse, mutect2
- CPS1 | c.4061G>T p.G1354V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV51805476; called by muse, mutect2
- CRB1 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66329415; called by muse, mutect2
- CREBBP | c.4413C>G p.I1471M | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52115526; called by muse, mutect2, varscan2
- CSPG4 | c.4640C>A p.S1547* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV57900225; called by muse, mutect2, varscan2
- CUL1 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100296940; called by muse, mutect2
- CUL4B | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV60690515; called by muse, mutect2, varscan2
- DHX38 | c.2152-1G>C p.X718_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as COSV51700340; called by muse, mutect2, varscan2
- DLC1 | c.899C>G p.S300* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV52323353; called by muse, mutect2, varscan2
- DPYSL3 | c.390G>C p.K130N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV100575304, COSV58330318; called by muse, mutect2, varscan2
- EHD2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs772336133, COSV54409147; called by muse, mutect2, varscan2
- ELP3 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV99834222; called by muse, mutect2
- ERICH3 | c.2056G>C p.E686Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV58609878, COSV58615836; called by muse, mutect2, varscan2
- ESRRA | c.830C>G p.S277* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV50007940; called by muse, mutect2, varscan2
- FANCB | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV60761403; called by muse, mutect2, varscan2
- FBN2 | c.4603G>A p.E1535K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52539266, COSV99327968; called by muse, mutect2
- FBXW10 | c.684G>T p.R228S | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV100111770; called by muse, mutect2
- FLG | c.10291C>T p.Q3431* | Nonsense Mutation (SNP) | VAF 30/310 reads (10%) | catalogued as COSV100911484, COSV64247101; called by muse, mutect2
- FLG | c.9812C>G p.S3271C | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs200552322, COSV64247108; called by muse, mutect2, varscan2
- FOS | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV57840246; called by muse, mutect2, varscan2
- GALK1 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as CM124972, CM124973, COSV56690452, COSV56692729; called by muse, mutect2, varscan2
- GEMIN5 | c.3269G>C p.R1090T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV53564015; called by muse, mutect2, varscan2
- GP5 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59879852; called by muse, mutect2, varscan2
- GRM5 | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59597042, COSV59606992; called by muse, mutect2
- GRWD1 | c.1047C>G p.F349L | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV53520624, COSV99474581; called by muse, mutect2
- GTF2E1 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV52205959; called by muse, mutect2
- HP | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); catalogued as COSV100577644; called by muse, mutect2
- HSPA9 | c.495G>C p.Q165H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51865960; called by muse, mutect2
- HTR3B | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs199833563, COSV52747099, COSV99491858; called by muse, mutect2, varscan2
- KBTBD2 | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); catalogued as COSV100406604, COSV58363615; called by muse, mutect2
- KDM4C | c.2693G>T p.R898I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV101185151, COSV67191212; called by muse, mutect2
- KIAA1210 | c.1526A>T p.D509V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV101274403; called by muse, mutect2
- KLKB1 | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as COSV52998576; called by muse, mutect2
- LATS1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs187759014, COSV53586271; called by muse, mutect2, varscan2
- LDB1 | c.235C>T p.Q79* (on ENST00000425280 / NM_001321612.2; = p.Q43* on NM_003893.5) | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as COSV63289848; called by muse, mutect2, varscan2
- LRP2 | c.9232C>G p.H3078D | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.041); catalogued as COSV55569648, COSV99787772; called by muse, mutect2, varscan2
- LRRK2 | c.5650C>T p.L1884F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as rs71653641, COSV54167333; called by muse, mutect2, varscan2
- MBTD1 | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV64504236; called by muse, mutect2, varscan2
- MERTK | c.2685G>C p.L895F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV54932985; called by muse, mutect2, varscan2
- MEX3B | c.549C>G p.I183M | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61664177; called by muse, mutect2, varscan2
- MMP1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV59510812; called by muse, mutect2
- MTOR | c.4401G>T p.M1467I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV63877064; called by muse, mutect2, varscan2
- MUC13 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.04); catalogued as COSV100222511; called by muse, mutect2
- MUC5AC | c.13992C>G p.I4664M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.13); catalogued as COSV100611536; called by muse, mutect2, varscan2
- NCBP3 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.225); catalogued as COSV50109979; called by muse, mutect2, varscan2
- NLRX1 | c.1895C>G p.S632C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52708598; called by muse, mutect2, varscan2
- NTMT1 | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.678); catalogued as COSV52965735; called by muse, mutect2, varscan2
- NUP160 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.609); catalogued as rs1565208990, COSV65854429; called by muse, mutect2, varscan2
- ODAM | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV68573375; called by muse, mutect2, varscan2
- PCDHB15 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.264); catalogued as rs1168737257, COSV51052730; called by muse, mutect2
- PDCD4 | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54525178; called by muse, mutect2
- PIMREG | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as rs1161537210, COSV51471767; called by muse, mutect2
- PLEKHG7 | c.1762C>G p.P588A | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as COSV100760185; called by muse, mutect2
- PLOD3 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs777238858, COSV56185384; called by muse, mutect2, varscan2
- PLXNA1 | c.1203G>C p.Q401H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV99304139; called by muse, mutect2, varscan2
- PNLDC1 | c.135G>C p.K45N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51707567; called by muse, mutect2, varscan2
- POGZ | c.3030C>G p.F1010L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.878); catalogued as COSV99305294; called by muse, mutect2
- PPM1F | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99601724; called by muse, mutect2, varscan2
- PSMC3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54080581; called by muse, mutect2, varscan2
- PTPN14 | c.3181C>T p.L1061F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV65284441; called by muse, mutect2
- QTRT1 | c.405G>C p.E135D | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV99139145; called by muse, mutect2
- RALGAPB | c.3334C>G p.L1112V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53442995; called by muse, mutect2, varscan2
- REXO5 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238387602, COSV54471101; called by muse, mutect2
- RRAD | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs774899242, COSV55339067; called by muse, mutect2, varscan2
- RTN3 | c.2679C>A p.F893L (on ENST00000377819 / NM_001265589.2; = p.F97L on NM_006054.4) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100380366; called by muse, mutect2
- SCRT1 | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59782145; called by muse, mutect2, varscan2
- SIRT5 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV63081611; called by muse, mutect2, varscan2
- SKAP2 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV61727060; called by muse, mutect2, varscan2
- SLC28A3 | c.1646C>A p.S549* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV66154674; called by muse, mutect2, varscan2
- SLC35F1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV64499348; called by muse, mutect2, varscan2
- SLCO2A1 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60488523; called by muse, mutect2
- SMC1A | c.3313G>C p.E1105Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447688; called by muse, mutect2, varscan2
- SPACA4 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as COSV99614457; called by muse, mutect2
- SRGAP1 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.041); catalogued as rs761572950, COSV61896851, COSV61902249; called by muse, mutect2, varscan2
- SRRM1 | c.2399G>A p.R800K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as COSV100105177; called by muse, mutect2
- STAMBPL1 | c.321G>C p.M107I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV64223016; called by muse, mutect2
- TACO1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1046248679, COSV99366583; called by muse, mutect2
- TAF6L | c.762C>G p.I254M | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53667726; called by muse, mutect2
- TASOR2 | c.3430G>C p.E1144Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV100051090; called by muse, mutect2
- TBC1D10B | c.1311C>G p.I437M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV59769688; called by mutect2, varscan2
- TENM2 | c.3169C>T p.H1057Y (on ENST00000518659 / NM_001122679.2; = p.H825Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV69139023; called by muse, mutect2, varscan2
- TMED5 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64757352; called by muse, mutect2, varscan2
- TMEM174 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as COSV99703836; called by muse, mutect2
- TRIO | c.6776G>A p.R2259Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.113); catalogued as rs750947029, COSV59992188; called by muse, mutect2, varscan2
- TROAP | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV99227034; called by muse, mutect2, varscan2
- TSR1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.156); catalogued as COSV52160994; called by muse, mutect2
- TTLL5 | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100091655; called by muse, mutect2
- UPF1 | c.2928G>C p.Q976H (on ENST00000599848 / NM_001297549.2; = p.Q965H on NM_002911.4) | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53200850; called by muse, mutect2, varscan2
- VPS13B | c.4592G>T p.G1531V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.927); catalogued as COSV62154182; called by muse, mutect2
- XIAP | c.1402C>G p.L468V | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100848988; called by muse, mutect2
- XKRX | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs771011999, COSV60707327, COSV60709090; called by muse, mutect2, varscan2
- YES1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV58850437; called by muse, mutect2
- ZAN | c.7564G>T p.E2522* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV61814599; called by muse, mutect2, varscan2
- ZBED9 | c.776C>G p.A259G | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101509400; called by muse, mutect2
- ZBTB10 | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs1412743184, COSV66948419; called by muse, mutect2, varscan2
- ZC3H11A | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59744369, COSV59749548; called by muse, mutect2, varscan2
- ZC3H15 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV61923416; called by muse, mutect2
- ZNF106 | c.3496C>T p.H1166Y | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.737); catalogued as rs770514798, COSV55521009; called by muse, mutect2, varscan2
- ZNF366 | c.1700-1G>C p.X567_splice | Splice Site (SNP) | VAF 13/69 reads (19%) | catalogued as COSV59218453; called by muse, mutect2, varscan2
- ZNF598 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1487662872, COSV70911493; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TRAV25 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ADGRE2 | c.1119G>A p.R373= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- B4GALT4 | c.381C>T p.L127= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs780383728, COSV63296324, COSV63296378; called by muse, mutect2, varscan2
- C1QTNF6 | c.762G>A p.E254= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV55397247; called by muse, mutect2, varscan2
- CDC14A | c.165G>C p.L55= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV100325999, COSV60559018; called by muse, mutect2
- CDHR3 | c.2298C>T p.V766= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs781595828, COSV58415650; called by mutect2, varscan2
- CHRNA3 | c.687C>T p.P229= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs144257258, COSV58776081; called by muse, mutect2, varscan2
- DAPK1 | c.2274G>A p.V758= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV63791120; called by muse, mutect2, varscan2
- ELOVL7 | c.845G>A p.*282= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1265423967, COSV101415648; called by muse, mutect2
- FANCL | c.177G>A p.L59= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV99287938; called by muse, mutect2
- FHOD1 | c.2511C>T p.S837= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1314361832, COSV50767254; called by muse, mutect2, varscan2
- FOS | c.585C>T p.F195= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100338601; called by muse, mutect2
- KDM3B | c.5253C>G p.L1751= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV99649770; called by muse, mutect2
- KRBA1 | c.1587G>A p.P529= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs759396276, COSV99753140; called by muse, mutect2, varscan2
- LARP4B | c.498C>T p.F166= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV60223384; called by muse, mutect2
- LRRC4 | c.762C>T p.V254= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1398616260, COSV50817487; called by muse, mutect2, varscan2
- LRRN2 | c.1692C>T p.L564= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV65784481; called by muse, mutect2, varscan2
- LYPD5 | c.270G>A p.A90= (on ENST00000377950 / NM_001031749.3; = p.A47= on NM_182573.2) | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as rs1309428256, COSV100935305; called by muse, mutect2
- MAL2 | c.247C>T p.L83= | Silent (SNP) | VAF 13/297 reads (4%) | catalogued as COSV99411195; called by muse, mutect2
- MTERF2 | c.921G>A p.L307= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as rs964124533, COSV53528692, COSV53528816; called by muse, mutect2
- MTMR12 | c.1200C>T p.L400= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV99374100; called by muse, mutect2
- MYCBPAP | c.1890C>T p.V630= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1244025321, COSV100089142; called by muse, mutect2, varscan2
- NEFH | c.1005G>A p.L335= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV60218319, COSV60219973; called by muse, mutect2, varscan2
- NFX1 | c.3174C>T p.V1058= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV65353010; called by muse, mutect2, varscan2
- PCDHA1 | c.1197C>T p.S399= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as COSV65373848, COSV65376393; called by muse, mutect2, varscan2
- PCP2 | c.321C>G p.L107= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs769723500, COSV60697868; called by muse, mutect2, varscan2
- PDE8A | c.2163G>A p.L721= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV59639900; called by muse, mutect2
- PEPD | c.675C>T p.L225= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV54895093; called by muse, mutect2, varscan2
- PHTF2 | c.525G>A p.L175= (on ENST00000248550 / NM_001366089.1; = p.L137= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV50337410; called by muse, mutect2, varscan2
- PPM1N | c.912G>A p.A304= | Silent (SNP) | VAF 13/146 reads (9%) | catalogued as rs764296211, COSV99839277; called by muse, mutect2
- PRAMEF14 | c.807C>T p.L269= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs1201662184; called by muse, varscan2
- RAB11FIP4 | c.1734C>G p.L578= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV57932253; called by muse, mutect2, varscan2
- ROR2 | c.186G>C p.L62= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV65222777; called by muse, mutect2, varscan2
- RPLP0 | c.540C>A p.I180= | Silent (SNP) | VAF 11/138 reads (8%) | catalogued as COSV99935477; called by muse, mutect2
- SCN7A | c.2184G>A p.V728= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV69274139; called by muse, mutect2, varscan2
- SHMT2 | c.1455C>G p.L485= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV61075097; called by muse, mutect2, varscan2
- SHOC1 | c.3690C>G p.V1230= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV59506380; called by muse, mutect2, varscan2
- SLC25A33 | c.369C>T p.F123= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs765213591, COSV57021593; called by muse, varscan2
- SMARCD1 | c.1116C>T p.I372= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV67411553, COSV67412976; called by muse, mutect2, varscan2
- SPINT1 | c.381C>T p.F127= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100689240; called by muse, mutect2, varscan2
- SSR2 | c.540G>A p.T180= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs769733555, COSV55304764; called by muse, mutect2, varscan2
- STXBP5L | c.1740C>G p.L580= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV99876543; called by muse, mutect2
- SUPT16H | c.1866C>T p.F622= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1198901365, COSV53527200; called by muse, mutect2
- TAP2 | c.570C>G p.A190= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV66488275; called by muse, mutect2
- TAS2R42 | c.624G>C p.V208= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- TYK2 | c.573C>G p.L191= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV53388350; called by muse, mutect2
- ZFP64 | c.1644G>C p.L548= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- ZNF48 | c.1110C>G p.L370= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV60784183; called by muse, mutect2, varscan2
- ZNF484 | c.87G>A p.Q29= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100214883; called by muse, mutect2
- CCDC33 | c.1938+415G>C | Intron (SNP) | VAF 11/63 reads (17%) | catalogued as COSV51434415; called by muse, mutect2, varscan2
- NOTCH2NLA | c.-191C>G | 5'UTR (SNP) | VAF 9/69 reads (13%) | catalogued as rs1467682956, COSV100757279, COSV100757455; called by muse, mutect2, varscan2
- OGFOD3 | c.824-1957G>A | Intron (SNP) | VAF 9/29 reads (31%) | catalogued as rs779485933, COSV57339074; called by muse, mutect2, varscan2
- UBXN1 | c.844+60G>A | Intron (SNP) | VAF 10/90 reads (11%) | catalogued as COSV53658511, COSV53658836; called by muse, mutect2, varscan2
